Gene-level copy-number profile of tumor specimen TCGA-WK-A8XO-01A from TCGA case TCGA-WK-A8XO, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.3 years (24,201 days).
Specimen TCGA-WK-A8XO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.47e3b38e-8036-4bf9-be8d-955262c40b85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WK-A8XO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/78d43832-9a7b-4912-8fac-a6000f6888e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 7,416; copy number 2: 46,437; copy number 3: 3,425; copy number 4: 2,159; copy number 5: 20; copy number 7: 2; copy number 8: 26; copy number 9: 30; copy number 10: 5; copy number 11: 7; copy number 12: 8; copy number 13: 4; copy number 15: 13; copy number 17: 4; copy number 22: 30; copy number 23: 2; copy number 24: 7; copy number 27: 38; copy number 29: 40; copy number 31: 4; copy number 33: 25; copy number 35: 1; copy number 37: 4; copy number 42: 42; copy number 43: 11; copy number 46: 6; copy number 56: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WK-A8XO-01A-11D-A37B-01): tumor purity 0.58, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:65,836,930–66,094,909, 2 genes: ADH5P4, NUFIP1P1.
- chr6:70,216,040–72,622,073, 40 genes (within-gene range 0–1): COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1, FO393414.2, FO393414.1, FO393414.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 332 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:45,303,910–45,340,893, 3 genes, copy number 12: LINC01144, HPDL, MUTYH.
- chr1:56,823,679–60,868,009, 43 genes, copy number 8–27 (within-gene range 2–27): AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1.
- chr1:153,658,703–153,923,360, 16 genes, copy number 8 (within-gene range 2–8): SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA, INTS3, AL513523.4, AL513523.3, SLC27A3, Y_RNA, GATAD2B, AL513523.2, AL513523.1, AL831737.1.
- chr1:156,893,698–157,598,085, 19 genes, copy number 5: PEAR1, LRRC71, ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52, AL357143.1, AL357143.2, AL138900.1, LINC02772, AL138900.2, AL732406.1, AL353899.1, FCRL5, FCRL4.
- chr1:169,957,942–169,990,196, 2 genes, copy number 7: RN7SL269P, MRPS10P1.
- chr1:171,600,621–172,468,831, 22 genes, copy number 9: MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105.
- chr2:239,048,168–240,468,076, 29 genes, copy number 12–22: HDAC4, MIR4440, MIR4441, AC017028.1, AC017028.2, MIR4269, MIR2467, HDAC4-AS1, AC023787.2, AC023787.3, AC023787.1, AC079612.1, AC079612.2, AC093802.2, AC093802.1, NDUFA10, MIR4786, OR6B2, OR6B3, OR9S24P, OR5S1P, COPS9, OTOS, AC124861.3, AC124861.2, AC124861.1, U3, GPC1, AC110619.1.
- chr5:120,710,698–120,710,840, 1 gene, copy number 5: RNU4-69P.
- chr11:17,349,053–17,476,879, 6 genes, copy number 9 (within-gene range 2–9): AC124798.2, NCR3LG1, AC124798.1, KCNJ11, ABCC8, SDHCP4.
- chr11:17,493,895–17,544,416, 1 gene, copy number 10 (within-gene range 2–10): USH1C.
- chr12:57,591,174–58,813,060, 42 genes, copy number 42 (within-gene range 2–42): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:66,563,524–66,569,194, 2 genes, copy number 23: OSBPL9P5, OSBPL9P4.
- chr12:67,440,998–67,590,771, 2 genes, copy number 15 (within-gene range 2–15): LINC02420, LINC02408.
- chr12:68,143,318–68,253,604, 4 genes, copy number 15–22: AC007458.1, IFNG, IL26, IL22.
- chr12:68,686,951–68,850,686, 8 genes, copy number 9–46: NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,212,108–71,586,310, 42 genes, copy number 10–29 (within-gene range 2–29): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1.
- chr12:75,926,213–76,033,932, 7 genes, copy number 24: AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4.
- chr12:78,793,526–79,503,396, 6 genes, copy number 11–35 (within-gene range 3–35): AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252.
- chr12:79,773,563–79,935,460, 1 gene, copy number 8 (within-gene range 3–8): PPP1R12A.
- chr12:79,878,305–80,380,879, 8 genes, copy number 8: RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261.
- chr12:81,257,975–81,759,553, 3 genes, copy number 29 (within-gene range 2–29): PPFIA2, PPFIA2-AS1, AC069228.1.
- chr12:81,953,719–83,152,190, 12 genes, copy number 10–29: LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25.
- chr12:84,147,304–85,342,912, 11 genes, copy number 13–56: AC090679.3, AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820.
- chr12:87,041,916–87,170,429, 2 genes, copy number 33: AC079597.1, RPL23AP68.
- chr12:88,049,016–88,199,887, 4 genes, copy number 31: CEP290, RNA5SP364, AC091516.1, TMTC3.
- chr12:90,576,402–90,889,917, 1 gene, copy number 43 (within-gene range 2–43): LINC02822.
- chr12:90,617,759–91,368,607, 10 genes, copy number 43 (within-gene range 2–43): AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA, LUM, DCN, AC007115.1, LINC02823.
- chr12:95,657,807–96,485,442, 23 genes, copy number 33 (within-gene range 2–33): NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11.
- chr12:102,953,289–102,960,513, 2 genes, copy number 11 (within-gene range 11–14): AC026108.1, ASCL1.

Autosomal genes at a single copy (total copy number 1): 7,416. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
